Somatic mutation profile of tumor specimen 0DF84O from CCDI case PBBPVR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 19.1 years (6,970 days).
Specimen 0DF84O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c16fd4ba-9166-48e6-b0b9-fc7000db50e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF84Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23b21492-d1f9-4496-a1dd-a4cfaafe429a

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 5, Intron 4, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 2, RNA 1, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 1813/1910 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 279/336 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN1 | c.1856C>T p.T619M | Missense Mutation (SNP) | VAF 203/710 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs202125007; called by muse, mutect2, varscan2
- CACNA2D4 | c.2317G>A p.V773M | Missense Mutation (SNP) | VAF 172/691 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as rs745376472; called by muse, mutect2, varscan2
- FRMPD2 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 64/812 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59720207; called by muse, mutect2
- FUT8 | c.578G>A p.R193Q (on ENST00000360689 / NM_001371534.1; = p.R30Q on NM_004480.4) | Missense Mutation (SNP) | VAF 131/509 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs566350467, COSV61283994, COSV61285229, COSV99051279; called by muse, mutect2, varscan2
- GRIP1 | c.2231G>A p.G744E (on ENST00000359742 / NM_001379345.1; = p.G692E on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 384/1326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs76102103, COSV54041607; called by muse, mutect2, varscan2
- KHDC3L | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 129/553 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.225); catalogued as rs968324083, COSV100951125; called by muse, mutect2, varscan2
- MALRD1 | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 248/1024 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs908498078; called by muse, mutect2, varscan2
- MASTL | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 138/684 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV60910610; called by muse, mutect2, varscan2
- RBP3 | c.3691C>A p.Q1231K | Missense Mutation (SNP) | VAF 17/610 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs1189295011; called by muse, mutect2
- SALL1 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 34/570 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs746684817; called by muse, mutect2
- TAF3 | c.1663_1665del p.E555del | In Frame Del (DEL) | VAF 271/1106 reads (25%) | catalogued as rs1564372994; called by mutect2, varscan2
- ZNF99 | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 64/458 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); catalogued as COSV68056654; called by muse, mutect2
- ATN1 | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 294/991 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BCORL1 | c.5073_5077dup p.E1693Gfs*10 | Frame Shift Ins (INS) | VAF 186/236 reads (79%) | called by mutect2, varscan2
- C3orf14 | c.159G>T p.R53S | Missense Mutation (SNP) | VAF 252/648 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CADM4 | c.890A>G p.H297R | Missense Mutation (SNP) | VAF 64/750 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.76); called by muse, mutect2
- CDC42EP4 | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2A | c.306_325del p.R103Lfs*10 | Frame Shift Del (DEL) | VAF 51/164 reads (31%) | called by mutect2, varscan2
- COG1 | c.1973A>G p.Q658R | Missense Mutation (SNP) | VAF 163/649 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELZ2 | c.615_618del p.D206Sfs*108 | Frame Shift Del (DEL) | VAF 219/567 reads (39%) | called by mutect2, varscan2
- KNDC1 | c.2906C>A p.T969K | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAOA | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRAMEF20 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 92/112 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RPRM | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 175/521 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SATL1 | c.697G>A p.G233S (on ENST00000395409; = p.G420S on NM_001012980.2) | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- SULT4A1 | c.516C>A p.Y172* | Nonsense Mutation (SNP) | VAF 157/293 reads (54%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.2124C>G p.S708R | Missense Mutation (SNP) | VAF 197/310 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TOP2A | c.3706A>T p.K1236* | Nonsense Mutation (SNP) | VAF 327/935 reads (35%) | called by muse, mutect2, varscan2
- UBE2O | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 94/745 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by mutect2, varscan2
- UBE2O | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 60/585 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBE2O | c.1246G>C p.D416H | Missense Mutation (SNP) | VAF 92/848 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- UBE2O | c.924G>T p.W308C | Missense Mutation (SNP) | VAF 81/693 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDR72 | c.2626G>T p.A876S | Missense Mutation (SNP) | VAF 251/662 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 30/849 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- CSPG5 | c.126C>G p.A42= | Silent (SNP) | VAF 32/632 reads (5%) | called by muse, mutect2
- EPRS1 | c.4494C>T p.G1498= | Silent (SNP) | VAF 227/641 reads (35%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2646C>T p.V882= | Silent (SNP) | VAF 302/770 reads (39%) | catalogued as rs779875195; called by muse, mutect2, varscan2
- SEC14L1 | c.1975C>T p.L659= | Silent (SNP) | VAF 159/656 reads (24%) | called by muse, mutect2, varscan2
- SYTL2 | c.1393C>T p.L465= | Silent (SNP) | VAF 145/249 reads (58%) | called by muse, mutect2, varscan2
- AC046195.1 | n.233C>A | RNA (SNP) | VAF 138/627 reads (22%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840637 C>T | 5'Flank (SNP) | VAF 401/960 reads (42%) | catalogued as rs756503903, COSV58332307; called by muse, mutect2, varscan2
- ARHGAP45 | c.2744+31G>A | Intron (SNP) | VAF 150/453 reads (33%) | catalogued as rs748847161; called by muse, mutect2, varscan2
- BRD8 | c.*68C>A | 3'UTR (SNP) | VAF 78/223 reads (35%) | called by muse, mutect2, varscan2
- MYH11 | c.2411+70C>T | Intron (SNP) | VAF 52/83 reads (63%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- SCRIB | c.4696-97C>T | Intron (SNP) | VAF 36/162 reads (22%) | catalogued as rs1347315292, COSV57592214; called by muse, mutect2, varscan2
- SPINK7 | c.*13C>A | 3'UTR (SNP) | VAF 188/617 reads (30%) | called by muse, mutect2, varscan2
